MMRF case MMRF_1785 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7dc81b4a-59e9-403a-ab1e-589bd2a24dad

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.6 years (23,227 days); ISS stage: II; Days to last known disease status: 1,080 days (3.0 years); Days to last follow up: 1,080 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 11 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 49 days; Days to treatment end: 217 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 223 days; Days to treatment end: 223 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 258 days; Days to treatment end: 258 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 259 days; Days to treatment end: 259 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 417 days (1.1 years); Days to treatment end: 417 days (1.1 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 418 days (1.1 years); Days to treatment end: 418 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 461 days (1.3 years); Days to treatment end: 553 days (1.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 639 days (1.7 years); Days to treatment end: 687 days (1.9 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 796 days (2.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 796 days (2.2 years); Days to treatment end: 884 days (2.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 796 days (2.2 years); Days to treatment end: 1,010 days (2.8 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 884 days (2.4 years); Days to treatment end: 888 days (2.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 888 days (2.4 years); Days to treatment end: 940 days (2.6 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,010 days (2.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 3): M Protein 4.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 56.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.54 mg/dL; Immunoglobulin G 2.8 g/L; Immunoglobulin A 46.3 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 3.8 µg/mL; Lactate Dehydrogenase 5.15 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 7.82 ×10⁹/L; Platelets 349 ×10⁹/L; Creatinine 58 µmol/L; Calcium 1.98 mmol/L; Albumin 21 g/L; Total Protein 9.2 g/dL; Glucose 6.3 mmol/L.
- Day 177 (ECOG 2): M Protein 6.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.08 mg/dL; Immunoglobulin G 8.5 g/L; Immunoglobulin A 9.46 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 3.88 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 95 µmol/L; Calcium 2.27 mmol/L; Albumin 38 g/L; Total Protein 7.5 g/dL; Glucose 5.8 mmol/L.
- Day 282 (ECOG 3): Serum Free Immunoglobulin Light Chain, Kappa 1.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 3.15 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 6.2 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 6.4 ×10⁹/L; Platelets 193 ×10⁹/L; Calcium 2.23 mmol/L; Glucose 5.5 mmol/L.
- Day 352 (ECOG 1): M Protein 4.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.6 mg/dL; Immunoglobulin G 21.9 g/L; Immunoglobulin A 4.06 g/L; Immunoglobulin M 0.51 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 83 µmol/L; Calcium 2.28 mmol/L; Albumin 34 g/L; Total Protein 7.6 g/dL; Glucose 6.2 mmol/L.
- Day 499 (ECOG 1): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.83 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 1.44 g/L; Immunoglobulin M 1.77 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 89 µmol/L; Calcium 2.32 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 5.7 mmol/L.
- Day 639: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.04 mg/dL; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 89 µmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL.
- Day 687: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.83 mg/dL; Immunoglobulin G 18.6 g/L; Immunoglobulin A 4.61 g/L; Immunoglobulin M 1.66 g/L; Lactate Dehydrogenase 3.95 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 86 µmol/L; Calcium 2.17 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL.
- Day 800: M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.61 mg/dL; Immunoglobulin G 19.4 g/L; Immunoglobulin A 4.65 g/L; Immunoglobulin M 1.18 g/L; Lactate Dehydrogenase 3.65 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 274 ×10⁹/L; Creatinine 112 µmol/L; Calcium 2.41 mmol/L; Albumin 40 g/L; Total Protein 7.9 g/dL.
- Day 884: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.12 mg/dL; Immunoglobulin G 8.16 g/L; Immunoglobulin A 2.01 g/L; Immunoglobulin M 0.63 g/L; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 91 µmol/L; Calcium 2.14 mmol/L; Albumin 33 g/L; Total Protein 5.6 g/dL.
- Day 968: M Protein 0 g/dL; Immunoglobulin G 9.46 g/L; Immunoglobulin A 4.23 g/L; Immunoglobulin M 0.57 g/L; Lactate Dehydrogenase 3.85 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 124 µmol/L; Calcium 2.26 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL.
- Day 1,080 (ECOG 2): M Protein 0 g/dL; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 112 µmol/L; Calcium 2.16 mmol/L; Albumin 37 g/L; Total Protein 5.7 g/dL.

Other clinical attributes
- Day -5: Weight: 76 kg; Height: 156 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.

Biospecimens (2 samples)
- Sample MMRF_1785_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1785_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
